Somatic mutation profile of tumor specimen MP2PRT-PATHCR-TMP1-A (aliquot MP2PRT-PATHCR-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATHCR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,364 days).
Specimen MP2PRT-PATHCR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db0dab8b-9e9c-44ab-8bb0-22340da29407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHCR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHCR-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75fbc5c6-8acd-4cd8-8e13-fabf156bfed0

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 42/193 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- DNAH3 | c.9854C>T p.T3285M | Missense Mutation (SNP) | VAF 146/372 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs765782793, COSV54545204; called by muse, mutect2, varscan2
- EHHADH | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs138013408, COSV51633114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRID1 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs377669879; called by muse, mutect2, varscan2
- GRM2 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs772536931; called by muse, varscan2
- H4C4 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 21/493 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs1394343410, COSV100534460; called by muse, mutect2
- KMT2A | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs782485631, COSV63284908, COSV63289756; called by muse, mutect2
- PCSK5 | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV101377469; called by muse, mutect2, varscan2
- PDE10A | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV63094378; called by muse, mutect2, varscan2
- PTPN23 | c.3773dup p.L1259Afs*14 | Frame Shift Ins (INS) | VAF 48/478 reads (10%) | catalogued as rs758419807; called by mutect2, pindel
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 13/463 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, mutect2
- THBS1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs760644149, COSV52952137; called by muse, mutect2, varscan2
- TMEM68 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.155); catalogued as COSV58169786; called by muse, mutect2
- WDR81 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 15/598 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1283176461; called by muse, mutect2
- AKAP6 | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG | c.3494T>C p.I1165T | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- HOXC13 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 26/730 reads (4%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.95); called by muse, mutect2
- NCF4 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 23/626 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA10 | c.2213T>C p.V738A | Missense Mutation (SNP) | VAF 196/546 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TBR1 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 19/583 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCOF1 | c.2824G>A p.D942N (on ENST00000377797 / NM_001135243.1; = p.D865N on NM_000356.4) | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FNBP1L | c.1311G>A p.K437= (on ENST00000271234 / NM_001164473.2; = p.K379= on NM_017737.5) | Silent (SNP) | VAF 52/328 reads (16%) | called by muse, mutect2, varscan2
- FREM2 | c.6273G>A p.A2091= | Silent (SNP) | VAF 161/476 reads (34%) | catalogued as rs769687764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAK | c.2064G>A p.L688= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- HRH1 | c.939G>A p.A313= | Silent (SNP) | VAF 34/353 reads (10%) | catalogued as rs369793859, COSV67955871; called by muse, mutect2, varscan2
- KMT2A | c.2079G>A p.R693= | Silent (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- NLRC3 | c.24G>A p.T8= | Silent (SNP) | VAF 177/473 reads (37%) | catalogued as rs751255172; called by muse, mutect2, varscan2
- PSME4 | c.78C>T p.F26= | Silent (SNP) | VAF 82/616 reads (13%) | catalogued as COSV66364404; called by muse, mutect2, varscan2
- TBC1D14 | c.1677A>G p.V559= | Silent (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- PKD1L2 | n.117G>T | RNA (SNP) | VAF 63/302 reads (21%) | called by muse, mutect2, varscan2
